TARGET case TARGET-15-SJMPAL040034 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ecbf0b99-f5ad-413c-abfa-2f9415d94059

Demographics
Sex at birth: male; Age at index: 7 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 7.1 years (2,585 days); Year of diagnosis: 2007; Days to last follow up: 3,395 days (9.3 years).

Follow-up (1 entry)
- Days to follow up: 3,395 days (9.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,395; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 130 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL040034-09A, TARGET-15-SJMPAL040034-09A.1, TARGET-15-SJMPAL040034-09A.2 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL040034-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 3395
- Protocol: Singapore
- WBC at Diagnosis: 130.3
- Initial Therapy: hybrid
- Karyotype: 47,XY,+X[13]/46,XY[7]
- WHO ALAL Classification: B/M
- WHO Dx: B/M
